Somatic mutation profile of tumor specimen C3N-00339-02 (aliquot CPT0020530009) from CPTAC case C3N-00339, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 45.4 years (16,577 days).
Specimen C3N-00339-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa2ed0b8-5aaa-4226-9642-d68432ce13ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00339-31 (Blood Derived Normal), aliquot CPT0020600002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e1c12e6-d7f2-41c3-b2c8-35f9b4aee031

The open-access MAF lists 57 somatic variants for this specimen: 32 protein-altering or splice-affecting, 13 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 13, Intron 6, 5'UTR 4, In Frame Del 2, Translation Start Site 1, In Frame Ins 1, Nonsense Mutation 1, Frame Shift Del 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 228/472 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 207/520 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CBLN4 | c.595T>C p.F199L | Missense Mutation (SNP) | VAF 162/307 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758409018; called by muse, mutect2, varscan2
- COL24A1 | c.3169C>T p.L1057F | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); catalogued as COSV65303368; called by muse, mutect2, varscan2
- ENO3 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.045); catalogued as rs779264075; called by muse, mutect2, varscan2
- HCAR2 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 86/409 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs758623640; called by muse, mutect2, varscan2
- IZUMO4 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs201920532, COSV61429974; called by muse, mutect2, varscan2
- KCNV1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 108/401 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1360181631; called by muse, mutect2, varscan2
- MYBPC2 | c.3077G>A p.R1026H | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs201843462; called by muse, mutect2, varscan2
- PCDHA8 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 136/386 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.056); catalogued as COSV100969618; called by muse, varscan2
- POLK | c.2390A>T p.H797L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1270118211; called by muse, mutect2, varscan2
- SEMA6A | c.2402C>T p.T801M | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.611); catalogued as rs372406609; called by muse, mutect2, varscan2
- SPRYD3 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV56855935; called by muse, mutect2, varscan2
- TUFT1 | c.685G>T p.V229F | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV61950396; called by muse, mutect2, varscan2
- UBE2J1 | c.758G>C p.R253P | Missense Mutation (SNP) | VAF 99/506 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.6); catalogued as COSV70561008; called by muse, mutect2, varscan2
- ZNF16 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99429742; called by muse, mutect2
- ZNF560 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs754071447, COSV56868095; called by muse, mutect2, varscan2
- AC138647.1 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ENAM | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 33/261 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HERPUD2 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 36/231 reads (16%) | called by muse, mutect2, varscan2
- KANSL2 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by mutect2, varscan2
- KCNT2 | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- NF1 | c.6676_6687del p.L2226_W2229del (on ENST00000358273 / NM_001042492.3; = p.L2205_W2208del on NM_000267.3) | In Frame Del (DEL) | VAF 21/243 reads (9%) | called by mutect2, pindel
- PARD3 | c.1400_1401del p.G467Dfs*39 | Frame Shift Del (DEL) | VAF 37/227 reads (16%) | called by mutect2, pindel, varscan2
- PEBP4 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, varscan2
- PIK3R1 | c.1210_1212del p.L404del (on ENST00000521381 / NM_181523.3; = p.L134del on NM_181504.4) | In Frame Del (DEL) | VAF 23/95 reads (24%) | called by mutect2, pindel, varscan2
- PRSS22 | c.701A>T p.E234V | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2
- RSAD2 | c.16C>G p.P6A | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2
- SEC31A | c.1781_1786dup p.M595_A596insGM (on ENST00000355196 / NM_001318120.1; = p.M556_A557insGM on NM_016211.4) | In Frame Ins (INS) | VAF 53/293 reads (18%) | called by mutect2, pindel, varscan2
- TRANK1 | c.4843C>G p.L1615V | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TRIM58 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 89/403 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP31 | c.1832T>G p.L611R | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEBPE | c.675C>T p.A225= | Silent (SNP) | VAF 38/466 reads (8%) | called by muse, mutect2
- CHST12 | c.192C>T p.S64= | Silent (SNP) | VAF 67/278 reads (24%) | catalogued as rs1173537712; called by muse, mutect2, varscan2
- FLG | c.6660T>C p.S2220= | Silent (SNP) | VAF 112/510 reads (22%) | catalogued as rs370632128; called by muse, mutect2, varscan2
- HCN3 | c.1212C>T p.G404= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as rs750043773, COSV61361045; called by muse, mutect2, varscan2
- NLRP1 | c.3228C>T p.D1076= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as rs139890811; called by muse, mutect2, varscan2
- NPTN | c.360C>T p.N120= | Silent (SNP) | VAF 65/238 reads (27%) | catalogued as rs1277120114, COSV54738030; called by muse, mutect2, varscan2
- PLPPR3 | c.1770C>T p.H590= (on ENST00000520876 / NM_001270366.2; = p.H618= on NM_024888.2) | Silent (SNP) | VAF 44/203 reads (22%) | catalogued as rs1316110796; called by muse, mutect2, varscan2
- POTEE | c.2169C>T p.G723= | Silent (SNP) | VAF 54/408 reads (13%) | catalogued as rs532506990; called by muse, mutect2, varscan2
- RPS27A | c.63T>C p.D21= | Silent (SNP) | VAF 98/364 reads (27%) | called by muse, mutect2, varscan2
- RYR2 | c.13806A>T p.R4602= | Silent (SNP) | VAF 35/202 reads (17%) | called by muse, mutect2, varscan2
- SIX2 | c.687C>T p.P229= | Silent (SNP) | VAF 108/359 reads (30%) | catalogued as rs746731462; called by muse, mutect2, varscan2
- VAT1L | c.939C>A p.I313= | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as rs200017287, COSV56815161; called by muse, mutect2, varscan2
- VXN | c.540C>T p.P180= | Silent (SNP) | VAF 70/236 reads (30%) | catalogued as rs768209161, COSV59686219; called by muse, mutect2, varscan2
- CEP350 | c.-120A>G | 5'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2
- EEF2KMT | c.159+35T>A | Intron (SNP) | VAF 47/330 reads (14%) | called by muse, mutect2, varscan2
- FIP1L1 | c.131-39del | Intron (DEL) | VAF 35/137 reads (26%) | called by mutect2, pindel, varscan2
- HMBS | c.160+79G>C | Intron (SNP) | VAF 48/224 reads (21%) | called by muse, mutect2
- L1CAM | c.2432-32A>G | Intron (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- MMP2 | c.*50C>T | 3'UTR (SNP) | VAF 73/232 reads (31%) | catalogued as rs756516690, COSV99527819; called by muse, mutect2, varscan2
- NUTM2D | c.-40G>A | 5'UTR (SNP) | VAF 150/1071 reads (14%) | catalogued as rs1354756859; called by muse, mutect2, varscan2
- RAB1B | chr11:66268614 A>T | 5'Flank (SNP) | VAF 16/86 reads (19%) | called by muse, varscan2
- RPS8 | c.-21C>T | 5'UTR (SNP) | VAF 59/233 reads (25%) | catalogued as rs757767727, COSV100785475; called by muse, mutect2, varscan2
- SHC1 | c.567-10C>T | Intron (SNP) | VAF 33/136 reads (24%) | called by muse, mutect2, varscan2
- TBCE | c.-16T>A | 5'UTR (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- TPM1 | c.772+82T>G | Intron (SNP) | VAF 17/272 reads (6%) | called by muse, mutect2
